Somatic mutation profile of tumor specimen TCGA-BK-A0CC-01A (aliquot TCGA-BK-A0CC-01A-21D-A272-09) from TCGA case TCGA-BK-A0CC, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 69.8 years (25,479 days).
Specimen TCGA-BK-A0CC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8952f1d8-c057-436c-92ed-17bbc55ffc47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BK-A0CC-10A (Blood Derived Normal), aliquot TCGA-BK-A0CC-10A-02D-A272-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9eac6229-9e7a-4a49-92f2-513acc86240e

The open-access MAF lists 54 somatic variants for this specimen: 39 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 27, Silent 15, Nonsense Mutation 5, Frame Shift Del 3, Splice Site 2, In Frame Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 57/110 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59042523, COSV59042723; called by muse, mutect2, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 99/146 reads (68%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- ATP9B | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs952837369, COSV56947200; called by muse, mutect2, varscan2
- CARMIL1 | c.3668G>A p.R1223H | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs775578827, COSV61515400; called by muse, mutect2, varscan2
- CDH7 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 40/78 reads (51%) | catalogued as rs766062933, COSV59885424; called by muse, mutect2, varscan2
- CR1L | c.535T>C p.Y179H | Missense Mutation (SNP) | VAF 11/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54325468; called by muse, mutect2
- DENND6B | c.334G>C p.D112H | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.516); catalogued as COSV101306063; called by muse, mutect2, varscan2
- DHDDS | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1383907275, COSV52575755; called by muse, mutect2, varscan2
- DLC1 | c.4529A>C p.K1510T (on ENST00000276297 / NM_001348081.2; = p.K1073T on NM_006094.5) | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV52301520; called by muse, mutect2, varscan2
- DNAH11 | c.3529C>G p.L1177V | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.903); catalogued as rs750181929, COSV60953781; called by muse, mutect2, varscan2
- DNM2 | c.2544-2A>G p.X848_splice (on ENST00000355667 / NM_001005360.3; = p.X844_splice on NM_004945.3) | Splice Site (SNP) | VAF 34/292 reads (12%) | catalogued as COSV99284094; called by muse, mutect2, varscan2
- E4F1 | c.360C>G p.I120M | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57038813; called by muse, mutect2, varscan2
- EPHA7 | c.1224C>G p.H408Q | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs145928664, COSV65182043, COSV65183842, COSV65190177; called by muse, mutect2, varscan2
- FAT1 | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 70/103 reads (68%) | catalogued as COSV71672105; called by muse, mutect2, varscan2
- FAT4 | c.11906-1G>C p.X3969_splice | Splice Site (SNP) | VAF 14/39 reads (36%) | catalogued as COSV58682550; called by muse, mutect2, varscan2
- IL3RA | c.256G>C p.A86P | Missense Mutation (SNP) | VAF 70/264 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as COSV58431048; called by muse, mutect2, varscan2
- MAIP1 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as rs1048972908, COSV54460546; called by muse, mutect2, varscan2
- MOCS1 | c.922T>C p.S308P | Missense Mutation (SNP) | VAF 14/297 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57935899; called by muse, mutect2
- NSUN4 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 82/142 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.142); catalogued as rs141622103; called by muse, mutect2, varscan2
- OGFOD3 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 34/178 reads (19%) | catalogued as COSV100234378; called by muse, mutect2, varscan2
- OR2T33 | c.896T>A p.L299Q | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58815191; called by muse, mutect2, varscan2
- OR4F15 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 81/213 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as COSV59968914; called by muse, mutect2, varscan2
- PCDH15 | c.3241G>C p.G1081R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.036); catalogued as COSV100213884, COSV57301824; called by muse, mutect2, varscan2
- PHLPP2 | c.3617G>A p.R1206Q | Missense Mutation (SNP) | VAF 158/218 reads (72%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.01); catalogued as rs1400230640, COSV62423299; called by muse, mutect2, varscan2
- PIK3C2B | c.4582G>A p.G1528S | Missense Mutation (SNP) | VAF 60/223 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as rs556813529, COSV65811100; called by muse, mutect2
- PLPP7 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs778837615, COSV100952562; called by muse, mutect2, varscan2
- SETBP1 | c.4202G>T p.R1401L | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs775975116, COSV56320530; called by muse, mutect2, varscan2
- SORCS3 | c.2940G>T p.Q980H | Missense Mutation (SNP) | VAF 40/211 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63794786, COSV63796067; called by muse, mutect2, varscan2
- SUGP2 | c.2845C>A p.P949T | Missense Mutation (SNP) | VAF 97/623 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58258071; called by muse, mutect2, varscan2
- TAX1BP1 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367927936; called by muse, mutect2, varscan2
- TSPYL1 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 118/554 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.398); catalogued as COSV63994045; called by muse, mutect2, varscan2
- UBL4A | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 136/195 reads (70%) | SIFT tolerated (0.35); PolyPhen benign (0.054); catalogued as rs782283486, COSV54836217; called by muse, mutect2, varscan2
- ZC3H7B | c.494_503del p.L165Pfs*36 | Frame Shift Del (DEL) | VAF 17/46 reads (37%) | catalogued as COSV60961730; called by mutect2, pindel, varscan2
- ZNF449 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 34/50 reads (68%) | catalogued as COSV59346904; called by muse, mutect2, varscan2
- ZRANB1 | c.1025G>T p.C342F | Missense Mutation (SNP) | VAF 85/206 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV62842306; called by muse, mutect2, varscan2
- AMOTL2 | c.1672_1674del p.Q558del | In Frame Del (DEL) | VAF 83/211 reads (39%) | called by mutect2, pindel, varscan2
- GRAMD1A | c.1811del p.I604Tfs*11 | Frame Shift Del (DEL) | VAF 51/271 reads (19%) | called by mutect2, pindel, varscan2
- KLHL41 | c.114del p.A39Qfs*11 | Frame Shift Del (DEL) | VAF 44/160 reads (28%) | called by mutect2, pindel, varscan2
- RADIL | c.2243_2245dup p.S748dup | In Frame Ins (INS) | VAF 30/94 reads (32%) | called by mutect2, pindel, varscan2
- ATP5F1B | c.318C>T p.S106= | Silent (SNP) | VAF 71/240 reads (30%) | catalogued as COSV56260852; called by muse, mutect2, varscan2
- ATP6V0D2 | c.804G>A p.A268= | Silent (SNP) | VAF 69/117 reads (59%) | catalogued as rs749834977, COSV53414562; called by muse, mutect2, varscan2
- DUSP29 | c.267C>T p.H89= | Silent (SNP) | VAF 36/230 reads (16%) | catalogued as COSV58300047; called by muse, mutect2, varscan2
- GPR31 | c.849C>T p.C283= | Silent (SNP) | VAF 72/164 reads (44%) | catalogued as COSV64761401; called by muse, mutect2, varscan2
- GPRIN2 | c.159C>T p.G53= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as rs782778481, COSV100966358; called by muse, mutect2, varscan2
- MMRN1 | c.3178A>C p.R1060= | Silent (SNP) | VAF 35/85 reads (41%) | catalogued as COSV53336981; called by muse, mutect2, varscan2
- MUC2 | c.3207G>A p.K1069= | Silent (SNP) | VAF 45/126 reads (36%) | called by muse, mutect2, varscan2
- NKIRAS1 | c.483C>T p.F161= | Silent (SNP) | VAF 30/140 reads (21%) | catalogued as COSV60667504; called by muse, mutect2, varscan2
- OCA2 | c.150C>T p.S50= | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as COSV62344526; called by muse, mutect2, varscan2
- SLC22A2 | c.1182C>A p.I394= | Silent (SNP) | VAF 33/138 reads (24%) | catalogued as COSV65266167, COSV65266823; called by muse, mutect2, varscan2
- SMG5 | c.2523G>A p.E841= | Silent (SNP) | VAF 98/210 reads (47%) | catalogued as COSV52745070, COSV99431537; called by muse, mutect2, varscan2
- TRAM1L1 | c.288A>C p.T96= | Silent (SNP) | VAF 9/150 reads (6%) | catalogued as COSV60291803; called by muse, mutect2
- TTC21A | c.849G>A p.L283= | Silent (SNP) | VAF 52/150 reads (35%) | catalogued as COSV57184777; called by muse, mutect2
- VCL | c.3045C>T p.L1015= (on ENST00000211998 / NM_014000.3; = p.L947= on NM_003373.4) | Silent (SNP) | VAF 40/152 reads (26%) | catalogued as COSV53007756; called by muse, mutect2, varscan2
- ZNF292 | c.4728A>G p.L1576= | Silent (SNP) | VAF 45/98 reads (46%) | catalogued as COSV60538923; called by muse, mutect2, varscan2
